Somatic mutation profile of tumor specimen TCGA-55-1596-01A (aliquot TCGA-55-1596-01A-01D-1040-01) from TCGA case TCGA-55-1596, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.8 years (20,381 days).
Specimen TCGA-55-1596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3ef5781-b308-4b21-b2ce-d137612b4279.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-1596-11A (Solid Tissue Normal), aliquot TCGA-55-1596-11A-01D-1040-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b21a13b1-96e6-4ba0-b2a4-1e0b5d9faccc

The open-access MAF lists 205 somatic variants for this specimen: 164 protein-altering or splice-affecting, 35 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 35, Nonsense Mutation 12, Frame Shift Del 5, Intron 4, Splice Region 3, Splice Site 3, RNA 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.246T>G p.F82L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs730881014, CM136416, COSV64170802, COSV64171107; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 18/28 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878853992, CM011965, COSV58824824, COSV58824977, COSV58825376; ClinVar: uncertain significance; called by muse, varscan2
- TP53 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 32/48 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63978674; called by muse, mutect2, varscan2
- ADAMTS1 | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV53173542, COSV53173955; called by muse, mutect2, varscan2
- ADAMTS20 | c.3151A>C p.N1051H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV67140825; called by muse, mutect2, varscan2
- ADAMTS3 | c.3331G>A p.G1111S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.001); catalogued as rs1180119030, COSV54404593; called by muse, mutect2, varscan2
- AHNAK2 | c.14005G>A p.E4669K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV60933183; called by muse, mutect2
- AKT3 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1173790414, COSV55636115; called by muse, mutect2, varscan2
- ALDH7A1 | c.568A>T p.I190F | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV68630245; called by muse, mutect2, varscan2
- ARHGEF10L | c.1132A>T p.I378F | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51431758; called by muse, mutect2, varscan2
- ASPM | c.6353G>T p.R2118M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV54140151; called by muse, mutect2, varscan2
- ASTN1 | c.798C>A p.S266R | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV56081439, COSV56088488; called by muse, mutect2, varscan2
- ATP13A5 | c.2765T>A p.L922Q | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60876397; called by muse, mutect2, varscan2
- AUTS2 | c.3461G>A p.R1154H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61433089; called by muse, mutect2, varscan2
- BAIAP3 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV60984631; called by muse, mutect2, varscan2
- BBS7 | c.202A>T p.R68W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52659978; called by muse, mutect2, varscan2
- BMP15 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV53142274; called by muse, mutect2, varscan2
- BRINP3 | c.2272G>C p.D758H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV66514748, COSV66523525, COSV66543301; called by muse, mutect2, varscan2
- BRINP3 | c.1558C>G p.R520G | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66532324, COSV66543305; called by muse, mutect2, varscan2
- CA8 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV58775048; called by muse, mutect2, varscan2
- CADM3 | c.662G>C p.R221T (on ENST00000368125 / NM_001127173.3; = p.R255T on NM_021189.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as COSV100930399, COSV63684559, COSV63687767; called by muse, mutect2, varscan2
- CALCRL | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV66477914; called by muse, mutect2, varscan2
- CBX2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1446155376, COSV53970391; called by muse, mutect2, varscan2
- CC2D2A | c.3338A>G p.H1113R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV67505931; called by muse, mutect2, varscan2
- CCDC178 | c.1724T>C p.I575T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV55767442; called by mutect2, varscan2
- CDH9 | c.449A>G p.H150R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.567); catalogued as COSV50515861; called by muse, mutect2, varscan2
- CDT1 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56350332, COSV99967206; called by muse, mutect2, varscan2
- CERKL | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); catalogued as rs1237603343, COSV59214667; called by muse, mutect2
- CFAP54 | c.8158G>T p.A2720S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV61575908; called by muse, mutect2, varscan2
- CHRM2 | c.266G>C p.W89S | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57786118; called by muse, mutect2, varscan2
- CKAP4 | c.1630A>G p.S544G | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65173329; called by muse, mutect2, varscan2
- CNGB3 | c.1911C>G p.I637M | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV60699651; called by muse, mutect2, varscan2
- CNIH1 | c.407+1G>C p.X136_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53595277; called by muse, mutect2, varscan2
- COL6A6 | c.3005T>A p.V1002D | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62039376; called by muse, mutect2, varscan2
- CSMD3 | c.10411A>T p.K3471* (on ENST00000297405 / NM_001363185.1; = p.K3302* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 43/75 reads (57%) | catalogued as COSV52339838; called by muse, mutect2, varscan2
- CSNK1G1 | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV57310744, COSV57314522; called by muse, mutect2, varscan2
- CYTH4 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | catalogued as COSV50632642, COSV50636574; called by muse, mutect2, varscan2
- DACH1 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV57521787; called by muse, mutect2, varscan2
- DACT1 | c.2180C>A p.S727* | Nonsense Mutation (SNP) | VAF 56/111 reads (50%) | catalogued as COSV60023876; called by muse, mutect2, varscan2
- DCC | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59133096, COSV59141256; called by muse, mutect2, varscan2
- DENND3 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52807586; called by muse, mutect2, varscan2
- DGKK | c.124G>C p.A42P | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.116); catalogued as COSV65709598; called by muse, mutect2, varscan2
- DIAPH2 | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61295242; called by muse, mutect2, varscan2
- DLL3 | c.393A>T p.L131F | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.648); catalogued as COSV52697023; called by muse, mutect2, varscan2
- DPYS | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.227); catalogued as rs1214914182, COSV60914324; called by muse, mutect2, varscan2
- EIF2AK3 | c.1918G>C p.V640L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as CM141523, COSV57552773; called by muse, mutect2
- ELFN2 | c.1436A>G p.E479G | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV68746884; called by muse, mutect2
- EPHA7 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.558); catalogued as COSV65193159; called by muse, mutect2, varscan2
- ESS2 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52819193; called by muse, mutect2, varscan2
- EVI5 | c.1654G>T p.D552Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV64830658; called by muse, mutect2, varscan2
- FAM186B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs544582250, COSV57722315; called by muse, mutect2, varscan2
- FAM214B | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100521192; called by muse, mutect2, varscan2
- FAM214B | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100521194; called by muse, mutect2, varscan2
- FKBP15 | c.327T>C p.Y109= | Splice Region (SNP) | VAF 6/9 reads (67%) | catalogued as rs369443598; called by muse, mutect2, varscan2
- FLG | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV64251179; called by muse, mutect2, varscan2
- FNDC3A | c.1575C>A p.Y525* (on ENST00000492622 / NM_001079673.2; = p.Y469* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV68135431; called by muse, mutect2, varscan2
- FSCB | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as COSV61216419; called by muse, mutect2, varscan2
- GABRQ | c.1550A>T p.K517M | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV64784241; called by muse, mutect2, varscan2
- GPAM | c.1753A>G p.I585V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62082858; called by muse, mutect2, varscan2
- GRIN2A | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100408525; called by muse, mutect2, varscan2
- GRIN2A | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV100408529; called by muse, mutect2, varscan2
- HARS1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV56909892; called by muse, mutect2, varscan2
- HEATR3 | c.1653T>G p.S551R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV53531966; called by muse, mutect2, varscan2
- HELZ | c.5239G>A p.E1747K | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.971); catalogued as COSV62381310; called by muse, mutect2, varscan2
- HM13 | c.540+2T>C p.X180_splice | Splice Site (SNP) | VAF 16/474 reads (3%) | catalogued as COSV59439932; called by muse, mutect2
- HMGCLL1 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV51453019; called by muse, mutect2, varscan2
- HSF4 | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50460358; called by muse, mutect2
- IFNA2 | c.245T>A p.M82K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66506025; called by muse, mutect2, varscan2
- IFNG | c.500A>T p.*167Lext*17 | Nonstop Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57492171; called by muse, mutect2
- IGHV1OR15-9 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs370092940; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 29/370 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1482563087; called by muse, mutect2
- IRX1 | c.665A>T p.E222V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV57362904; called by muse, mutect2, varscan2
- ITPKB | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.1); catalogued as rs573808314, COSV55259094, COSV55270905; called by muse, mutect2, varscan2
- ITPR2 | c.6397G>A p.D2133N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV67277187; called by muse, mutect2, varscan2
- JARID2 | c.1914G>T p.Q638H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100521397; called by muse, mutect2
- KCNC2 | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs746501735, COSV54361296; called by muse, mutect2, varscan2
- KCNK18 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV100571980, COSV57973523; called by muse, mutect2, varscan2
- KCNK18 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs745940715, COSV100571981; called by muse, mutect2, varscan2
- KPRP | c.1370T>C p.I457T | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64223145; called by muse, mutect2, varscan2
- KRT79 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV57942620; called by muse, mutect2, varscan2
- KRTAP13-1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62664557; called by muse, mutect2, varscan2
- LARP4B | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100295102; called by muse, mutect2, varscan2
- LARP4B | c.247T>A p.W83R | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100295107; called by muse, mutect2, varscan2
- LIPI | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as rs922068615, COSV60716663; called by muse, mutect2, varscan2
- LRIT1 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV64512545, COSV64513235; called by muse, mutect2, varscan2
- LRP1B | c.13049G>T p.R4350L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.982); catalogued as rs200243152, COSV67281222; called by muse, mutect2, varscan2
- LRP1B | c.2036C>A p.A679D | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101253350; called by muse, mutect2, varscan2
- LRP1B | c.1199A>T p.Q400L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV101253354; called by muse, mutect2, varscan2
- LRP1B | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV67184239, COSV67203754; called by muse, mutect2, varscan2
- LRRC7 | c.1623C>A p.C541* (on ENST00000651989 / NM_001370785.2; = p.C508* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as COSV50648537; called by muse, mutect2, varscan2
- LRRN2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as rs745491741, COSV65784936; called by muse, mutect2, varscan2
- LUC7L | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1407054032, COSV53461015; called by muse, mutect2, varscan2
- MAGEB10 | c.364T>A p.L122M | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV63310332, COSV63312867; called by muse, mutect2, varscan2
- MAN2B1 | c.2078T>G p.F693C | Missense Mutation (SNP) | VAF 107/152 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55475708; called by muse, mutect2, varscan2
- MARCHF10 | c.1050T>G p.S350R | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60890858; called by muse, mutect2, varscan2
- MKRN3 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as rs1186354016, COSV58812576; called by muse, mutect2, varscan2
- MYH8 | c.5095G>T p.E1699* | Nonsense Mutation (SNP) | VAF 60/96 reads (63%) | catalogued as COSV67973750; called by muse, mutect2, varscan2
- NELL1 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.787); catalogued as COSV54296468, COSV54333818; called by muse, mutect2, varscan2
- OLFML2B | c.1906C>A p.L636M | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV54200971, COSV54201384; called by muse, varscan2
- OPRPN | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.097); catalogued as COSV68193713; called by muse, mutect2, varscan2
- OR10G7 | c.117del p.N40Tfs*7 | Frame Shift Del (DEL) | VAF 31/268 reads (12%) | catalogued as COSV100390048; called by mutect2, pindel, varscan2
- OR1D5 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73859629, COSV73859693; called by muse, mutect2, varscan2
- OR2L3 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV63456545; called by muse, mutect2, varscan2
- OR2T3 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV62083923; called by muse, mutect2, varscan2
- PC | c.2110A>G p.I704V | Missense Mutation (SNP) | VAF 96/128 reads (75%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.711); catalogued as rs772717561, COSV58994685; called by muse, mutect2, varscan2
- PCDH15 | c.4306C>T p.P1436S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs765570619, COSV100214050, COSV57405736; called by muse, mutect2, varscan2
- PCDH15 | c.2869G>T p.G957* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV57265314, COSV57360873; called by muse, mutect2, varscan2
- PCDH15 | c.1274G>C p.R425T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.348); catalogued as COSV57405796; called by muse, mutect2, varscan2
- PCDHB8 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs1554280867, COSV99175921; called by muse, mutect2, varscan2
- PDZRN4 | c.2460G>T p.E820D (on ENST00000402685 / NM_001164595.2; = p.E562D on NM_013377.4) | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54219346; called by muse, mutect2, varscan2
- PGR | c.860C>A p.A287E | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); catalogued as COSV54809821, COSV54811903; called by muse, mutect2, varscan2
- PKHD1L1 | c.8288G>T p.C2763F | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV65755127; called by muse, mutect2, varscan2
- PRDM9 | c.1083C>A p.Y361* | Nonsense Mutation (SNP) | VAF 46/112 reads (41%) | catalogued as COSV57014303; called by muse, mutect2, varscan2
- PRPF6 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV53879741; called by muse, mutect2, varscan2
- PTPRK | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63891277, COSV63908719; called by muse, mutect2
- PTPRT | c.1569C>A p.Y523* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | catalogued as COSV62028253; called by muse, mutect2, varscan2
- RASAL2 | c.5A>G p.Q2R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.775); catalogued as rs1484706187, COSV62724592; called by muse, mutect2, varscan2
- RPGRIP1L | c.2294A>G p.H765R | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV50919593; called by muse, mutect2, varscan2
- RPL4 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV57183755; called by muse, mutect2, varscan2
- RSPO4 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs772877858, COSV54084311; called by muse, mutect2, varscan2
- RYR2 | c.10494G>A p.L3498= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as COSV63718920; called by muse, mutect2, varscan2
- SAXO2 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV59755591; called by muse, mutect2, varscan2
- SCN3A | c.1380G>A p.Q460= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as COSV51826690; called by muse, mutect2
- SCYL1 | c.2345G>C p.R782P | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54216297; called by muse, varscan2
- SEC23B | c.1511+1G>A p.X504_splice | Splice Site (SNP) | VAF 102/275 reads (37%) | catalogued as COSV52724449; called by muse, mutect2, varscan2
- SFMBT1 | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867253711, COSV56256226; called by muse, mutect2
- SLC26A6 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749502519, COSV51170359; called by muse, mutect2, varscan2
- SLC39A12 | c.1676T>C p.I559T (on ENST00000377369 / NM_001145195.2; = p.I522T on NM_152725.3) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV66202965; called by muse, mutect2, varscan2
- SLC4A5 | c.1633G>T p.D545Y | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61033759; called by muse, mutect2, varscan2
- SLC4A8 | c.2104T>A p.F702I | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60658950; called by muse, mutect2, varscan2
- SLCO5A1 | c.1644T>G p.H548Q | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV52669527; called by muse, mutect2, varscan2
- SLX4IP | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV57952143; called by muse, mutect2, varscan2
- SMARCA4 | c.3067G>C p.E1023Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV60800796, COSV60811024; called by muse, mutect2, varscan2
- SNX25 | c.1215A>T p.E405D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV53019233; called by muse, mutect2, varscan2
- SPTA1 | c.4844G>T p.S1615I | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV63760810; called by muse, mutect2, varscan2
- TAF1L | c.4272C>A p.F1424L | Missense Mutation (SNP) | VAF 87/142 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV54271235; called by muse, mutect2, varscan2
- TAF2 | c.677C>G p.T226S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.518); catalogued as COSV65421868; called by muse, mutect2, varscan2
- TDRD10 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs751439221, COSV52725914, COSV52726142; called by muse, mutect2, varscan2
- THBS2 | c.3340C>G p.L1114V | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs1398623994, COSV64682590; called by muse, mutect2, varscan2
- THSD7A | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV70267647; called by muse, mutect2, varscan2
- TICRR | c.5308T>A p.L1770M | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51540517, COSV51547891; called by muse, mutect2, varscan2
- TMEM82 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV53818795; called by muse, mutect2, varscan2
- TNRC6C | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV56954001; called by muse, mutect2, varscan2
- TRDMT1 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1317699591, COSV58321148; called by muse, mutect2, varscan2
- TRPC1 | c.1132A>T p.R378* (on ENST00000476941 / NM_001251845.2; = p.R344* on NM_003304.4) | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV56430937; called by muse, mutect2, varscan2
- TXNDC11 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51603928; called by muse, varscan2
- UNC13A | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs1186328118, COSV53213133; called by muse, mutect2, varscan2
- URB2 | c.3739A>T p.M1247L | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV51059612; called by muse, mutect2, varscan2
- VWF | c.8183C>T p.T2728I | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV54636725, COSV99780600; called by muse, mutect2
- WDR89 | c.945C>G p.S315R | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV50828093; called by muse, mutect2, varscan2
- XPNPEP1 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV59171429; called by muse, mutect2, varscan2
- ZFHX4 | c.4409G>T p.W1470L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.554); catalogued as rs772763644, COSV51500105; called by muse, mutect2, varscan2
- ZFPM2 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.115); catalogued as COSV65876409; called by muse, mutect2
- ZNF438 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 87/156 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59201691; called by muse, mutect2, varscan2
- ZNF479 | c.442T>C p.C148R | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV58644338; called by muse, mutect2, varscan2
- ATP8B2 | c.1731del p.M577Ifs*4 (on ENST00000672630; = p.M544Ifs*4 on NM_001367934.1 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel
- IGKV1D-8 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- MYH13 | c.4680del p.S1560Rfs*8 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- NOTUM | c.527dup p.N176Kfs*11 | Frame Shift Ins (INS) | VAF 13/111 reads (12%) | called by pindel, varscan2*
- OR10G9 | c.117del p.N40Tfs*7 | Frame Shift Del (DEL) | VAF 225/487 reads (46%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.1714_1724del p.K572Gfs*75 | Frame Shift Del (DEL) | VAF 56/119 reads (47%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1440A>T p.Q480H | Missense Mutation (SNP) | VAF 268/554 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, varscan2
- UGT2A1 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.1038A>G p.T346= (on ENST00000506720 / NM_001322402.2; = p.T278= on NM_015236.6) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV72274412; called by mutect2, varscan2
- ARFGEF1 | c.3750A>T p.P1250= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV51618478; called by muse, mutect2, varscan2
- ARHGEF2 | c.345C>T p.T115= (on ENST00000361247 / NM_001162383.2; = p.T88= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV58117988; called by muse, mutect2, varscan2
- AXIN1 | c.2118G>A p.Q706= | Silent (SNP) | VAF 96/249 reads (39%) | catalogued as COSV51989114; called by muse, mutect2, varscan2
- BCL2L10 | c.159C>A p.A53= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- CDIP1 | c.171G>T p.P57= | Silent (SNP) | VAF 69/157 reads (44%) | catalogued as COSV54859581, COSV54862013; called by muse, mutect2, varscan2
- CLCA2 | c.681C>T p.T227= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV65289022; called by muse, mutect2, varscan2
- COL11A1 | c.441C>A p.A147= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV62200372; called by muse, varscan2
- CSMD3 | c.10660T>C p.L3554= (on ENST00000297405 / NM_001363185.1; = p.L3385= on NM_052900.3) | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV52339817; called by muse, mutect2, varscan2
- DAAM2 | c.2916G>C p.R972= (on ENST00000274867 / NM_001201427.2; = p.R971= on NM_015345.3) | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV51342448, COSV51421437, COSV99224280; called by muse, mutect2, varscan2
- EEF1A1 | c.420T>G p.A140= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100303215; called by muse, mutect2, varscan2
- FAT3 | c.4719G>A p.A1573= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs745526724, COSV53070950; called by muse, mutect2, varscan2
- GEM | c.339A>G p.T113= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs933690241, COSV52599445; called by muse, mutect2, varscan2
- IARS1 | c.3726C>T p.P1242= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs777464643, COSV65117425; called by muse, mutect2, varscan2
- KLHL14 | c.801C>A p.A267= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV63835910; called by muse, mutect2, varscan2
- LDHC | c.36A>G p.L12= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as rs928689193, COSV55006307; called by muse, mutect2, varscan2
- LRP1B | c.2037C>A p.A679= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV101253349; called by muse, mutect2, varscan2
- LTK | c.1317C>T p.L439= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as rs1566868411, COSV53029592; called by muse, mutect2, varscan2
- LTN1 | c.1365G>A p.Q455= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs745744443, COSV63735504; called by muse, mutect2
- MAP3K9 | c.726G>T p.L242= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV67123128; called by muse, mutect2, varscan2
- MARF1 | c.705G>A p.G235= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV60023094; called by muse, mutect2, varscan2
- MRPL19 | c.513C>T p.V171= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1011697396, COSV62568216; called by muse, mutect2, varscan2
- MYLK | c.4281A>G p.K1427= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs772237691, COSV60624349; called by muse, mutect2, varscan2
- OR2T34 | c.216G>T p.A72= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as COSV100170264; called by muse, mutect2, varscan2
- PCNX1 | c.1827T>C p.S609= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV53103355; called by muse, mutect2, varscan2
- PHF2 | c.837C>G p.S279= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV63684410; called by muse, mutect2, varscan2
- PTPRF | c.1392G>A p.K464= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV63449479; called by muse, mutect2, varscan2
- RASAL2 | c.888G>T p.L296= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV62724596; called by muse, mutect2, varscan2
- SPIRE1 | c.876G>T p.R292= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV59163226; called by muse, mutect2, varscan2
- SULF1 | c.1866C>A p.P622= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV52695101; called by muse, mutect2, varscan2
- THSD7A | c.1113C>A p.P371= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV70274058; called by muse, mutect2, varscan2
- TTN | c.13881A>T p.T4627= (on ENST00000591111; = p.T3700= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV60391558; called by muse, mutect2, varscan2
- WNT7B | c.165G>T p.R55= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs761116915, COSV59752646; called by muse, mutect2, varscan2
- ZNF687 | c.1185G>A p.R395= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV55022218; called by muse, mutect2, varscan2
- ZNF831 | c.4812C>T p.P1604= | Silent (SNP) | VAF 25/177 reads (14%) | catalogued as COSV64038813; called by muse, mutect2, varscan2
- DNAJA4 | c.132+1391T>G | Intron (SNP) | VAF 38/55 reads (69%) | catalogued as COSV100655124; called by muse, mutect2, varscan2
- KIF1B | c.2115+7353_2115+7356dup | Intron (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- PLCB1 | c.2524-6199C>T | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as rs772153298, COSV62056056; called by muse, mutect2, varscan2
- PLCB1 | c.2524-6198G>C | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.47A>T | RNA (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- XIST | n.8761A>G | RNA (SNP) | VAF 14/18 reads (78%) | called by muse, mutect2, varscan2
